Somatic mutation profile of tumor specimen TCGA-DU-6396-01A (aliquot TCGA-DU-6396-01A-11D-1705-08) from TCGA case TCGA-DU-6396, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 31.3 years (11,427 days).
Specimen TCGA-DU-6396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 364f9d02-df36-4bdc-9fde-6592ea7bf516.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6396-10A (Blood Derived Normal), aliquot TCGA-DU-6396-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf3937c6-f51c-47d5-8e0e-865b2e7ef468

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 29, Silent 11, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 49/145 reads (34%) | hotspot (GDC flag); catalogued as rs919106518, COSV64870782; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/80 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 25/35 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG2 | c.1307T>A p.F436Y (on ENST00000379869 / NM_001079858.3; = p.F433Y on NM_005756.4) | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV61339443; called by muse, mutect2, varscan2
- APOL4 | c.793C>T p.R265* (on ENST00000352371 / NM_145660.2; = p.R262* on NM_030643.4) | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as rs200035805; called by muse, mutect2, varscan2
- ARAP1 | c.4343G>C p.R1448P (on ENST00000393609 / NM_001040118.2; = p.R1203P on NM_015242.4) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV100502012, COSV61991540; called by muse, mutect2, varscan2
- BARD1 | c.1721G>A p.G574D | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53612684; called by muse, mutect2, varscan2
- CHST11 | c.840G>C p.E280D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57988484; called by muse, mutect2, varscan2
- DCAKD | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60831333; called by muse, mutect2, varscan2
- EEF1D | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1292991211, COSV52785551; called by muse, mutect2, varscan2
- EIF4G3 | c.3242G>A p.G1081D | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51683636; called by muse, mutect2, varscan2
- FASTKD1 | c.1195C>T p.L399F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747909377, COSV71624357; called by muse, mutect2, varscan2
- FGD6 | c.2981T>C p.V994A | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59693713; called by muse, mutect2, varscan2
- GZF1 | c.2044C>T p.L682F | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV57636380; called by muse, mutect2
- IL16 | c.3547C>T p.R1183C (on ENST00000302987 / NM_172217.5; = p.R482C on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770059879, COSV57155041; called by muse, mutect2, varscan2
- KIF2B | c.402G>T p.R134S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as COSV52131178; called by muse, mutect2, varscan2
- LIM2 | c.319dup p.S107Ffs*59 (on ENST00000596399 / NM_001161748.2; = p.S149Ffs*59 on NM_030657.4) | Frame Shift Ins (INS) | VAF 26/45 reads (58%) | catalogued as rs1490674848; called by mutect2, varscan2
- MKI67 | c.3652G>A p.A1218T | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.284); catalogued as rs1240030607, COSV64074763; called by muse, mutect2, varscan2
- MUC17 | c.5148C>A p.D1716E | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV60290502; called by muse, mutect2, varscan2
- MYO5C | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV55907166, COSV55912385; called by muse, mutect2, varscan2
- NCKAP5 | c.5345C>G p.P1782R | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as COSV58447191; called by muse, mutect2, varscan2
- OR52M1 | c.871A>T p.N291Y | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64172089; called by muse, mutect2, varscan2
- POLA1 | c.828G>C p.E276D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV66886851; called by muse, mutect2, varscan2
- RYR2 | c.10075T>C p.F3359L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV63688755; called by muse, mutect2, varscan2
- SCGN | c.486C>G p.D162E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV58545798; called by muse, mutect2, varscan2
- SLC38A10 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55845999; called by muse, mutect2, varscan2
- THSD7B | c.3910T>C p.Y1304H (on ENST00000272643; = p.Y1302H on NM_001316349.2) | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV55693398; called by muse, mutect2, varscan2
- TRO | c.2632G>A p.V878I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51502369; called by muse, mutect2, varscan2
- TUBA3C | c.464A>G p.E155G | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV67139381; called by muse, mutect2, varscan2
- UGT2B4 | c.1049A>C p.N350T | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV59317712; called by muse, mutect2, varscan2
- ZNF385B | c.212A>T p.K71I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV69803291; called by muse, mutect2, varscan2
- ZNF638 | c.5723G>A p.G1908D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV52488392; called by muse, mutect2
- ANKRA2 | c.861A>G p.L287= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV57141074; called by muse, mutect2, varscan2
- CFAP251 | c.2391C>T p.T797= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV56611049; called by muse, mutect2, varscan2
- CREB3L3 | c.897C>G p.L299= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1041364646, COSV50179756; called by muse, mutect2, varscan2
- HLA-DOA | c.462C>G p.V154= | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as COSV57714447; called by muse, mutect2, varscan2
- KCNG2 | c.888C>G p.L296= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV60268183; called by muse, mutect2
- LRFN1 | c.1674C>G p.R558= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV50448531; called by muse, mutect2, varscan2
- SAT1 | c.180G>A p.P60= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV63380715; called by muse, mutect2, varscan2
- SPTBN4 | c.5526C>T p.D1842= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs374234251; called by muse, mutect2, varscan2
- TBX1 | c.516C>T p.Y172= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs772390067, COSV60352511; called by muse, mutect2, varscan2
- TBX5 | c.1476C>T p.G492= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs369034176; called by muse, mutect2, varscan2
- TFAP2D | c.489G>T p.L163= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV50419538; called by muse, mutect2, varscan2
